MMRF case MMRF_1867 — Multiple Myeloma CoMMpass Study (MMRF-COMMPASS)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Plasma Cell Tumors; Primary site: Hematopoietic and reticuloendothelial systems. Index date (day 0 for every day count below): first treatment.
https://portal.gdc.cancer.gov/cases/119c1bf9-97a6-46ad-a22e-02425fb649f5

Demographics
Sex at birth: female; Race: white; Ethnicity: not hispanic or latino; Age at index: 58 years; Vital status: Alive.

Diagnoses (1)
1. Multiple myeloma: ICD-O-3 morphology code: 9732/3; Tissue or organ of origin: Bone marrow; Site of resection or biopsy: Bone marrow; Age at diagnosis: 58.6 years (21,416 days); ISS stage: I; Days to last known disease status: 1,078 days (3.0 years); Days to last follow up: 1,078 days (3.0 years).
   Treatment given: Therapeutic agents: Bortezomib; Regimen or line of therapy: First line of therapy; Days to treatment start: 1 day; Days to treatment end: 71 days.
   Treatment given: Therapeutic agents: Cyclophosphamide + Dexamethasone; Regimen or line of therapy: First line of therapy; Days to treatment start: 1 day; Days to treatment end: 91 days.
   Treatment given: Therapeutic agents: Cyclophosphamide; Regimen or line of therapy: First line of therapy; Days to treatment start: 92 days; Days to treatment end: 92 days.
   Treatment given: Therapeutic agents: Dexamethasone; Regimen or line of therapy: First line of therapy; Days to treatment start: 92 days; Days to treatment end: 93 days.
   Treatment given: Therapeutic agents: Bortezomib; Regimen or line of therapy: First line of therapy; Days to treatment start: 121 days; Days to treatment end: 124 days.
   Treatment given: Treatment type: Stem Cell Transplantation, Autologous; Regimen or line of therapy: First line of therapy; Days to treatment start: 132 days; Days to treatment end: 132 days.
   Treatment given: Therapeutic agents: Lenalidomide; Regimen or line of therapy: First line of therapy; Days to treatment start: 233 days.

Molecular and laboratory tests (laboratory values one line per visit day; values rounded to 3 significant figures where GDC's unit conversion carried more)
- Day -7 (ECOG 1): M Protein 2.5 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 1.38 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 28.4 mg/dL; Immunoglobulin G 8.72 g/L; Immunoglobulin A 1.71 g/L; Immunoglobulin M 0.65 g/L; Beta 2 Microglobulin 2.89 µg/mL; Lactate Dehydrogenase 3.55 µkat/L; Hemoglobin 8.68 mmol/L; Leukocytes 5.5 ×10⁹/L; Absolute Neutrophil 3.3 ×10⁹/L; Platelets 271 ×10⁹/L; Creatinine 61 µmol/L; Calcium 2.44 mmol/L; Albumin 44 g/L; Total Protein 7.3 g/dL; Glucose 9.6 mmol/L; C-Reactive Protein 0.25 mg/dL.
- Day 93 (ECOG 1): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 0.961 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.87 mg/dL; Immunoglobulin G 5.62 g/L; Immunoglobulin A 0.77 g/L; Immunoglobulin M 0.42 g/L; Beta 2 Microglobulin 2.26 µg/mL; Lactate Dehydrogenase 4.12 µkat/L; Hemoglobin 7.94 mmol/L; Leukocytes 4 ×10⁹/L; Absolute Neutrophil 2.7 ×10⁹/L; Platelets 300 ×10⁹/L; Creatinine 61 µmol/L; Calcium 2.31 mmol/L; Albumin 43.6 g/L; Total Protein 6.6 g/dL; Glucose 8.2 mmol/L.
- Day 159 (ECOG 1): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 1.19 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1 mg/dL; Immunoglobulin G 9.04 g/L; Immunoglobulin A 1 g/L; Immunoglobulin M 0.31 g/L; Beta 2 Microglobulin 1.8 µg/mL; Lactate Dehydrogenase 3.82 µkat/L; Hemoglobin 6.88 mmol/L; Leukocytes 4.2 ×10⁹/L; Absolute Neutrophil 2.1 ×10⁹/L; Platelets 181 ×10⁹/L; Creatinine 63 µmol/L; Blood Urea Nitrogen 0.9 mmol/L; Calcium 1.79 mmol/L; Albumin 44.8 g/L; Total Protein 7.4 g/dL; Glucose 5.4 mmol/L.
- Day 250 (ECOG 1): M Protein 2.3 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 1.26 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.07 mg/dL; Immunoglobulin G 9.04 g/L; Immunoglobulin A 1 g/L; Immunoglobulin M 0.31 g/L; Lactate Dehydrogenase 3.13 µkat/L; Hemoglobin 7.75 mmol/L; Leukocytes 4.9 ×10⁹/L; Absolute Neutrophil 3.1 ×10⁹/L; Platelets 203 ×10⁹/L; Creatinine 63 µmol/L; Calcium 2.27 mmol/L; Albumin 38 g/L; Total Protein 7.1 g/dL; Glucose 5.4 mmol/L.
- Day 343 (ECOG 1): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 2.06 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.68 mg/dL; Immunoglobulin G 11.3 g/L; Immunoglobulin A 1.78 g/L; Immunoglobulin M 0.41 g/L; Lactate Dehydrogenase 3.17 µkat/L; Hemoglobin 8.06 mmol/L; Leukocytes 3.2 ×10⁹/L; Absolute Neutrophil 1.8 ×10⁹/L; Platelets 190 ×10⁹/L; Creatinine 76 µmol/L; Calcium 2.38 mmol/L; Albumin 42 g/L; Total Protein 7.3 g/dL; Glucose 5.4 mmol/L.
- Day 399 (ECOG 1): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 1.83 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.66 mg/dL; Immunoglobulin G 10.7 g/L; Immunoglobulin A 1.85 g/L; Immunoglobulin M 0.41 g/L; Lactate Dehydrogenase 3 µkat/L; Hemoglobin 8.25 mmol/L; Leukocytes 3 ×10⁹/L; Absolute Neutrophil 1.4 ×10⁹/L; Platelets 178 ×10⁹/L; Creatinine 91 µmol/L; Blood Urea Nitrogen 5.4 mmol/L; Calcium 2.47 mmol/L; Albumin 39 g/L; Total Protein 7.3 g/dL; Glucose 10.1 mmol/L.
- Day 511 (ECOG 1): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 2.52 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.99 mg/dL; Immunoglobulin G 11.5 g/L; Immunoglobulin A 2.54 g/L; Immunoglobulin M 0.42 g/L; Lactate Dehydrogenase 2.58 µkat/L; Hemoglobin 8.06 mmol/L; Leukocytes 2.9 ×10⁹/L; Absolute Neutrophil 1.6 ×10⁹/L; Platelets 162 ×10⁹/L; Creatinine 78 µmol/L; Blood Urea Nitrogen 4.4 mmol/L; Calcium 2.3 mmol/L; Albumin 37 g/L; Total Protein 7.3 g/dL; Glucose 10 mmol/L.
- Day 628 (ECOG 1): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 5.11 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 3.7 mg/dL; Immunoglobulin G 16.9 g/L; Immunoglobulin A 5.05 g/L; Immunoglobulin M 0.42 g/L; Lactate Dehydrogenase 2.83 µkat/L; Hemoglobin 8.06 mmol/L; Leukocytes 4.2 ×10⁹/L; Absolute Neutrophil 2 ×10⁹/L; Platelets 191 ×10⁹/L; Creatinine 72 µmol/L; Blood Urea Nitrogen 4.4 mmol/L; Calcium 2.31 mmol/L; Albumin 40.9 g/L; Total Protein 7.9 g/dL.
- Day 686 (ECOG 1): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 4.55 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 3.22 mg/dL; Immunoglobulin G 17 g/L; Immunoglobulin A 4.32 g/L; Immunoglobulin M 0.4 g/L; Lactate Dehydrogenase 2.52 µkat/L; Hemoglobin 8.43 mmol/L; Leukocytes 3.2 ×10⁹/L; Absolute Neutrophil 1.4 ×10⁹/L; Platelets 182 ×10⁹/L; Creatinine 71 µmol/L; Blood Urea Nitrogen 4.5 mmol/L; Calcium 2.4 mmol/L; Albumin 48.2 g/L; Total Protein 7.8 g/dL; Glucose 6.5 mmol/L.
- Day 798 (ECOG 1): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 4.21 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 2.78 mg/dL; Immunoglobulin G 14.4 g/L; Immunoglobulin A 4.02 g/L; Immunoglobulin M 0.38 g/L; Lactate Dehydrogenase 2.42 µkat/L; Hemoglobin 7.94 mmol/L; Leukocytes 3 ×10⁹/L; Absolute Neutrophil 1.6 ×10⁹/L; Platelets 157 ×10⁹/L; Creatinine 78 µmol/L; Blood Urea Nitrogen 4.7 mmol/L; Calcium 2.33 mmol/L; Albumin 39.6 g/L; Total Protein 7.4 g/dL.
- Day 910 (ECOG 1): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 4.21 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 2.35 mg/dL; Immunoglobulin G 16.5 g/L; Immunoglobulin A 5.2 g/L; Immunoglobulin M 0.36 g/L; Lactate Dehydrogenase 2.58 µkat/L; Hemoglobin 7.81 mmol/L; Leukocytes 3.5 ×10⁹/L; Absolute Neutrophil 1.5 ×10⁹/L; Platelets 159 ×10⁹/L; Creatinine 79 µmol/L; Blood Urea Nitrogen 5 mmol/L; Calcium 2.28 mmol/L; Albumin 40.6 g/L; Total Protein 7.8 g/dL.
- Day 966 (ECOG 1): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 4.58 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 2.64 mg/dL; Immunoglobulin G 15.6 g/L; Immunoglobulin A 5.23 g/L; Immunoglobulin M 0.35 g/L; Lactate Dehydrogenase 2.47 µkat/L; Hemoglobin 7.38 mmol/L; Leukocytes 2.6 ×10⁹/L; Absolute Neutrophil 1.2 ×10⁹/L; Platelets 182 ×10⁹/L; Creatinine 85 µmol/L; Blood Urea Nitrogen 4.7 mmol/L; Calcium 2.25 mmol/L; Albumin 36.9 g/L; Total Protein 7.3 g/dL; Glucose 7.2 mmol/L.
- Day 1,078 (ECOG 1): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 4.42 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 3.23 mg/dL; Immunoglobulin G 15.1 g/L; Immunoglobulin A 5.1 g/L; Immunoglobulin M 0.42 g/L; Lactate Dehydrogenase 2.35 µkat/L; Hemoglobin 7.38 mmol/L; Leukocytes 3 ×10⁹/L; Absolute Neutrophil 1.3 ×10⁹/L; Platelets 154 ×10⁹/L; Creatinine 88 µmol/L; Blood Urea Nitrogen 4.9 mmol/L; Calcium 2.24 mmol/L; Albumin 39.1 g/L; Total Protein 7.3 g/dL; Glucose 7.2 mmol/L.

Other clinical attributes
- Day -7: Weight: 86 kg; Height: 157 cm.

Family history
- Relative with cancer history: no.

Biospecimens (2 samples)
- Sample MMRF_1867_1_BM_CD138pos: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS; Days to sample procurement: -7 days.
- Sample MMRF_1867_1_PB_Whole: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS; Days to sample procurement: -7 days.
